Somatic mutation profile of tumor specimen 0DCFVT from CCDI case PBBJGY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Spinal cord; Age at diagnosis: 5.8 years (2,116 days).
Specimen 0DCFVT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb2a88f4-7a13-40eb-92fc-9a3b2eb52d65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCFVN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c0ece84-2b93-4feb-a9c4-705b953fef6e

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H2BC7 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 22/668 reads (3%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs954407765; called by muse, mutect2
- ASIC2 | c.1327A>G p.S443G | Missense Mutation (SNP) | VAF 16/540 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2
